Somatic mutation profile of tumor specimen 0DV5SG from CCDI case PBCMHN, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Orbit, NOS; Age at diagnosis: 2.2 years (815 days).
Specimen 0DV5SG: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d2b19f8c-3016-4f57-81b5-e094fd848e7a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DV5RV (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/87797ec5-3a3c-4e5f-b35b-2ae83ca9432d

The open-access MAF lists 16 somatic variants for this specimen: 12 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 3, Intron 1, Frame Shift Ins 1, Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 535/838 reads (64%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.525); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ATR | c.4051C>G p.R1351G | Missense Mutation (SNP) | VAF 360/1180 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as COSV63389400; called by muse, mutect2, varscan2
- CELSR1 | c.2116G>A p.V706M | Missense Mutation (SNP) | VAF 182/488 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760664139, COSV53100640; called by muse, mutect2, varscan2
- MYO16 | c.1312C>G p.L438V | Missense Mutation (SNP) | VAF 185/717 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as COSV51807053; called by muse, mutect2, varscan2
- NCLN | c.1151C>T p.T384M | Missense Mutation (SNP) | VAF 129/423 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs772829975; called by muse, mutect2, varscan2
- OAS1 | c.403G>C p.V135L | Missense Mutation (SNP) | VAF 180/528 reads (34%) | SIFT tolerated (0.3); PolyPhen benign (0.062); catalogued as COSV52538597; called by muse, mutect2, varscan2
- TASP1 | c.1121C>G p.T374R | Missense Mutation (SNP) | VAF 28/886 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61813240; called by muse, mutect2
- ZNF462 | c.6715G>A p.V2239M | Missense Mutation (SNP) | VAF 142/374 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.04); catalogued as rs772048238, COSV52936495; called by muse, mutect2, varscan2
- ERICH6B | c.1199dup p.N400Kfs*3 | Frame Shift Ins (INS) | VAF 179/833 reads (21%) | called by mutect2, varscan2
- NF1 | c.6420_6427+18del p.X2140_splice (on ENST00000358273 / NM_001042492.3; = p.X2119_splice on NM_000267.3) | Splice Site (DEL) | VAF 90/431 reads (21%) | called by mutect2, varscan2
- PTPRQ | c.219T>A p.D73E (on ENST00000616559; = p.D31E on NM_001145026.2) | Missense Mutation (SNP) | VAF 318/875 reads (36%) | SIFT tolerated (0.44); PolyPhen benign (0.003); called by muse, mutect2
- SLCO4A1 | c.1023C>G p.Y341* | Nonsense Mutation (SNP) | VAF 241/725 reads (33%) | called by muse, mutect2, varscan2
- LRRK1 | c.3627G>A p.P1209= | Silent (SNP) | VAF 154/464 reads (33%) | catalogued as rs780134153; called by muse, mutect2, varscan2
- OR4Q2 | c.489C>A p.L163= | Silent (SNP) | VAF 142/418 reads (34%) | called by muse, mutect2, varscan2
- PTGS2 | c.48T>C p.H16= | Silent (SNP) | VAF 215/342 reads (63%) | catalogued as rs752671561; called by muse, mutect2, varscan2
- KLRC2 | c.585-38T>G | Intron (SNP) | VAF 141/422 reads (33%) | called by muse, mutect2, varscan2
